Somatic mutation profile of tumor specimen MMRF_1518_3_BM_CD138pos (aliquot MMRF_1518_3_BM_CD138pos_T1_KBS5U_L05551) from MMRF case MMRF_1518, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,200 days).
Specimen MMRF_1518_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8017e3c0-ef74-4f45-8669-1d6b793dbd06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1518_3_PB_Whole (Blood Derived Normal), aliquot MMRF_1518_3_PB_Whole_C3_KBS5U_L05573; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b2ab906-7a2f-4d46-a548-ce3af5f9cf5f

The open-access MAF lists 278 somatic variants for this specimen: 94 protein-altering or splice-affecting, 45 silent, 139 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, 3'UTR 63, Silent 45, Intron 37, 5'Flank 13, 5'UTR 10, 3'Flank 10, Nonsense Mutation 10, RNA 6, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as COSV99717630; called by muse, mutect2, varscan2
- CDHR1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV60563323; called by muse, mutect2
- DENND4B | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs868393573; called by muse, mutect2
- DLX2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1457752592; called by muse, varscan2
- ENPP7 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as COSV60387477; called by muse, mutect2
- EPHB1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67654980, COSV67659512, COSV67664485; called by muse, mutect2, varscan2
- GREM2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.135); catalogued as COSV58957130; called by muse, mutect2
- GRIN2D | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54380226; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- KCNT1 | c.2039C>T p.T680M (on ENST00000488444; = p.T699M on NM_020822.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.238); catalogued as rs538197009, COSV53700849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L3MBTL3 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV62384340; called by muse, mutect2, varscan2
- MAB21L4 | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV56743988; called by muse, mutect2, varscan2
- MACROH2A2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs571470231; called by mutect2, varscan2
- MIS18BP1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs144218247; called by muse, mutect2, varscan2
- NFXL1 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 41/72 reads (57%) | catalogued as COSV61200196; called by muse, mutect2, varscan2
- NFYC | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58125969; called by muse, mutect2, varscan2
- PCDH17 | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV64973901; called by muse, mutect2
- PPFIA3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61951924, COSV61955098; called by muse, mutect2, varscan2
- PTPRQ | c.3399C>G p.I1133M (on ENST00000616559; = p.I1091M on NM_001145026.2) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs1343207437; called by muse, mutect2, varscan2
- RANBP3L | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751770258, COSV56954604; called by muse, mutect2, varscan2
- SELP | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1557963517; called by muse, mutect2, varscan2
- SETD1B | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.013); catalogued as rs1235576836; called by muse, mutect2
- SGIP1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs200265343; called by muse, mutect2
- THAP7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by muse, mutect2, varscan2
- USH2A | c.84A>G p.I28M | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as rs1270426964; called by muse, mutect2
- USP10 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1176111401; called by muse, mutect2
- VWDE | c.656dup p.N219Kfs*11 | Frame Shift Ins (INS) | VAF 19/166 reads (11%) | catalogued as rs907015274; called by mutect2, varscan2
- ZFHX3 | c.6446G>A p.R2149H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51717751; called by muse, mutect2
- ZNF175 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs772615101; called by mutect2, varscan2
- ZNF320 | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 8/196 reads (4%) | catalogued as COSV67088667; called by muse, mutect2
- ACBD5 | c.196G>A p.E66K (on ENST00000375888 / NM_001352568.1; = p.E68K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADAMTS14 | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- AFAP1L2 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 88/159 reads (55%) | called by muse, varscan2
- ANO2 | c.497G>A p.G166E (on ENST00000356134 / NM_001278597.3; = p.G170E on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASPM | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ATXN10 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C5 | c.4943G>A p.W1648* | Nonsense Mutation (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- CACNA1C | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 11/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDKL5 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- DGKI | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- DOCK7 | c.3595G>T p.D1199Y (on ENST00000635253 / NM_001367561.1; = p.D1168Y on NM_033407.3) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- DPYSL4 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DYNC1I2 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FES | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FGA | c.374_377dup p.N128Lfs*13 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- FOXO6 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2
- GRHPR | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRPEL2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HMGCS2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- IGLV2-23 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ITGA7 | c.847C>A p.L283M (on ENST00000555728; = p.L239M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KIF5A | c.17A>T p.N6I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- KLHL4 | c.1650G>T p.W550C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA3 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.407); called by muse, mutect2
- LAMB3 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LHFPL2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRTM2 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGOH | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2
- MEX3C | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- NFIX | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NHLRC3 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMUR2 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NPBWR1 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.183); called by muse, mutect2
- OR1N1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2A12 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PARP14 | c.440_443dup p.S149Ffs*7 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.11283C>A p.C3761* | Nonsense Mutation (SNP) | VAF 61/109 reads (56%) | called by muse, mutect2, varscan2
- PKLR | c.1031T>G p.I344S | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPIL6 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRSS35 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- PTPN22 | c.2114T>G p.F705C (on ENST00000359785 / NM_001193431.2; = p.F650C on NM_012411.5) | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RC3H2 | c.2441A>T p.D814V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RGS22 | c.3758T>C p.L1253S | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- RNF138 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- RPL21 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RSBN1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2
- SEC61A1 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SERPINB5 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SLC25A27 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLC4A8 | c.3091A>T p.K1031* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- SNX1 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SYNJ1 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TBX21 | c.1371A>T p.E457D | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- TIE1 | c.2932A>T p.R978W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC5 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTC30B | c.578A>T p.N193I | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- UBR7 | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by mutect2, varscan2
- USP35 | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- VPS53 | c.1891G>A p.V631I (on ENST00000571805 / NM_001366253.2; = p.V602I on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- VWA8 | c.2426+2T>C p.X809_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- WDR83 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- WDR90 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- ZNF407 | c.5135A>T p.K1712I | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA13 | c.2769C>T p.I923= | Silent (SNP) | VAF 89/137 reads (65%) | called by muse, mutect2, varscan2
- ABCC3 | c.3834C>T p.R1278= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- AC099489.1 | c.3765C>T p.Y1255= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1008651523; called by mutect2, varscan2
- ADAM23 | c.2214C>T p.L738= | Silent (SNP) | VAF 73/112 reads (65%) | catalogued as rs748943848, COSV52216648; called by muse, mutect2, varscan2
- ADCY9 | c.3303C>T p.Y1101= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs141385288; called by muse, mutect2, varscan2
- BTBD11 | c.1230G>A p.L410= | Silent (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- CACNG1 | c.144G>A p.A48= | Silent (SNP) | VAF 85/276 reads (31%) | catalogued as rs144676810; called by muse, mutect2, varscan2
- CCNQ | c.600G>T p.L200= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- CERS5 | c.129C>T p.R43= | Silent (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- CSMD3 | c.8163A>T p.V2721= | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- CUL3 | c.711A>T p.V237= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV52363782; called by muse, mutect2
- DDX60 | c.1965C>T p.C655= | Silent (SNP) | VAF 13/375 reads (3%) | called by muse, mutect2
- DENND1A | c.735C>T p.Y245= | Silent (SNP) | VAF 30/117 reads (26%) | called by muse, mutect2, varscan2
- DOCK10 | c.4857C>T p.A1619= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs1219456600, COSV51379124; called by muse, mutect2, varscan2
- FAM91A1 | c.1239A>T p.S413= | Silent (SNP) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- FOXQ1 | c.30G>A p.A10= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs767809988; called by mutect2, varscan2
- FOXQ1 | c.264G>A p.A88= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- HCN3 | c.138G>A p.R46= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as COSV100751883; called by muse, mutect2, varscan2
- HIP1 | c.1215G>A p.L405= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs781989600; called by muse, mutect2, varscan2
- IRGQ | c.1560G>A p.L520= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs764545585; called by muse, mutect2, varscan2
- JKAMP | c.354C>T p.I118= (on ENST00000554271 / NM_001284201.1; = p.I104= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- KCTD1 | c.717G>A p.L239= | Silent (SNP) | VAF 74/160 reads (46%) | catalogued as rs764837166; called by muse, mutect2, varscan2
- KLK12 | c.192C>T p.S64= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs774600833; called by muse, mutect2, varscan2
- MAFA | c.309C>T p.A103= | Silent (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- MEAK7 | c.888C>T p.L296= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as rs143458469; called by muse, mutect2, varscan2
- OR5H6 | c.144G>A p.L48= (on ENST00000642105; = p.L32= on NM_001005479.2) | Silent (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- PAFAH1B3 | c.87G>A p.R29= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- PCDH11X | c.2733A>G p.L911= | Silent (SNP) | VAF 22/338 reads (7%) | catalogued as COSV53457776; called by muse, mutect2
- PCDHGA10 | c.249G>C p.P83= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- PDE4DIP | c.3174G>A p.E1058= | Silent (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- PKHD1 | c.4227G>T p.V1409= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- PPIL6 | c.540A>T p.G180= | Silent (SNP) | VAF 64/240 reads (27%) | called by muse, varscan2
- SCYL2 | c.2352C>T p.F784= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs745664030; called by muse, mutect2, varscan2
- SELE | c.1077C>T p.I359= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV60974854; called by muse, mutect2, varscan2
- SLC27A5 | c.909G>A p.K303= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- SP8 | c.1311G>A p.T437= (on ENST00000361443 / NM_198956.4; = p.T455= on NM_182700.6) | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs1297485590; called by muse, mutect2, varscan2
- STXBP2 | c.18G>A p.L6= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- SUN1 | c.579G>A p.E193= (on ENST00000405266 / NM_001367651.1; = p.E143= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as rs1187432251; called by muse, mutect2
- TGS1 | c.69G>A p.K23= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs761903979; called by muse, mutect2, varscan2
- TMEM219 | c.333G>C p.L111= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- TSC1 | c.3132G>A p.E1044= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- UTRN | c.4377C>T p.H1459= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs766145602, COSV100839961; called by muse, mutect2, varscan2
- VPS18 | c.1296C>T p.F432= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV99592899; called by muse, mutect2
- WDR89 | c.234T>C p.F78= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- ZAN | c.3708G>A p.Q1236= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- A1CF | chr10:50806506 C>T | 3'Flank (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- AAK1 | c.*10180G>A | 3'UTR (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- AAK1 | c.-115C>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as rs1231359629; called by muse, mutect2
- AANAT | chr17:76465965 T>C | 5'Flank (SNP) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- ABAT | c.*465C>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ABCC1 | c.*590G>C | 3'UTR (SNP) | VAF 31/45 reads (69%) | called by muse, mutect2, varscan2
- ABR | c.1962-127T>G | Intron (SNP) | VAF 9/92 reads (10%) | called by mutect2, varscan2
- AC010928.1 | n.260T>A | RNA (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- AC016596.1 | chr5:56002104 G>T | 5'Flank (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- AC027612.1 | n.1856G>A | RNA (SNP) | VAF 11/72 reads (15%) | catalogued as rs982832244; called by muse, mutect2, varscan2
- AC103996.1 | chr15:93821053 T>C | 3'Flank (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- ACTC1 | c.*115C>G | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- ACTL6B | c.102+52A>C | Intron (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- ACTR1B | c.441-49G>T | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs995669545; called by muse, mutect2, varscan2
- ADH6 | chr4:99204561 C>A | 3'Flank (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- ANAPC1 | c.*1082C>T | 3'UTR (SNP) | VAF 18/264 reads (7%) | catalogued as rs1206568448; called by muse, mutect2
- ANKRD13C | c.1215+49A>T | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- ANKRD13D | c.*1530G>A | 3'UTR (SNP) | VAF 83/121 reads (69%) | catalogued as COSV57386361; called by muse, mutect2, varscan2
- ANKRD52 | c.*4129A>T | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- ANKRD6 | c.1612+196T>C | Intron (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ARHGEF9 | c.*1632G>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | catalogued as rs1556297611; called by muse, mutect2
- ARL15 | c.*189C>T | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- ARMC8 | c.1135-1413G>C | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- ATP13A4 | chr3:193554930 C>A | 5'Flank (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- BAIAP3 | c.-20A>G | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- BIRC8 | n.993G>C | RNA (SNP) | VAF 37/76 reads (49%) | catalogued as COSV101461363, COSV70346632; called by muse, mutect2, varscan2
- BRK1 | c.-12C>T | 5'UTR (SNP) | VAF 41/58 reads (71%) | catalogued as COSV99845147; called by muse, mutect2, varscan2
- C14orf132 | chr14:96087071 C>T | 3'Flank (SNP) | VAF 12/59 reads (20%) | catalogued as rs369440049; called by muse, mutect2, varscan2
- CACNA1I | c.*1548C>G | 3'UTR (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- CACNG8 | c.*5070A>G | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- CALHM1 | c.-25G>T | 5'UTR (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- CAMK4 | c.*5806G>C | 3'UTR (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2, varscan2
- CAPN8 | c.307+11570G>A | Intron (SNP) | VAF 26/253 reads (10%) | catalogued as rs1482237759; called by mutect2, varscan2
- CCAR2 | c.2728-140G>A | Intron (SNP) | VAF 50/92 reads (54%) | called by mutect2, varscan2
- CCDC57 | c.*83G>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CELF2 | c.*3210G>C | 3'UTR (SNP) | VAF 37/66 reads (56%) | catalogued as rs1050946; called by muse, mutect2, varscan2
- CHM | c.*3357T>G | 3'UTR (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- CHMP1A | c.*360C>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- CHRND | chr2:232526051 C>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- COL25A1 | c.-162C>T | 5'UTR (SNP) | VAF 10/144 reads (7%) | catalogued as rs888537021; called by muse, mutect2
- CRACR2B | c.277+112A>G | Intron (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.101+88G>T | Intron (SNP) | VAF 23/146 reads (16%) | catalogued as COSV53938306; called by muse, mutect2, varscan2
- CYGB | chr17:76538232 C>A | 5'Flank (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- DNAI4 | c.*53C>G | 3'UTR (SNP) | VAF 90/202 reads (45%) | called by muse, varscan2
- DNAJC10 | c.*2493G>C | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- DNAJC18 | c.*371C>T | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- DOCK2 | c.5166+17G>A | Intron (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- EEA1 | c.*884G>C | 3'UTR (SNP) | VAF 44/115 reads (38%) | catalogued as rs538576413; called by muse, mutect2, varscan2
- EIF4G2 | c.*681_*684dup | 3'UTR (INS) | VAF 11/103 reads (11%) | called by mutect2, pindel
- ERLIN2 | chr8:37735236 C>T | 5'Flank (SNP) | VAF 7/120 reads (6%) | catalogued as rs1344065358; called by muse, mutect2
- EXTL3 | c.*489C>T | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- F2RL1 | c.*1267G>T | 3'UTR (SNP) | VAF 70/109 reads (64%) | called by muse, mutect2, varscan2
- FAT1 | c.13139-1359A>T | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- FBXO9 | c.*211dup | 3'UTR (INS) | VAF 44/90 reads (49%) | catalogued as rs921789811; called by mutect2, varscan2
- FIGN | c.*3889T>A | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- GOSR2 | chr17:46940741 C>T | 3'Flank (SNP) | VAF 21/39 reads (54%) | catalogued as rs1432881074; called by muse, mutect2, varscan2
- GRIA4 | c.247+1753_247+1756del | Intron (DEL) | VAF 16/41 reads (39%) | catalogued as rs1219454473; called by pindel, varscan2
- HCAR1 | c.*83C>T | 3'UTR (SNP) | VAF 21/182 reads (12%) | catalogued as rs374948591; called by muse, mutect2, varscan2
- ICA1L | c.-7-152C>A | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- IFNAR1 | c.*2689C>T | 3'UTR (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- IPO9 | c.*1554G>C | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- ITGA7 | c.*207C>G | 3'UTR (SNP) | VAF 4/107 reads (4%) | called by muse, mutect2
- KMT5C | c.570+867A>G | Intron (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- KRT78 | c.*1182C>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- MALRD1 | c.5030-2482C>A | Intron (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- MAP4 | c.292+4167C>G | Intron (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- MBP | chr18:76978804 C>T | 3'Flank (SNP) | VAF 4/8 reads (50%) | catalogued as rs534663999; called by muse, varscan2
- MFSD14A | c.*1012A>C | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2
- MIR124-2HG | n.134G>T | RNA (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- MRPL37 | c.*29C>T | 3'UTR (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- MTO1 | chr6:73461648 T>C | 5'Flank (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- MYO10 | c.-193G>A | 5'UTR (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- NASP | c.-18C>T | 5'UTR (SNP) | VAF 90/178 reads (51%) | catalogued as COSV63113706; called by muse, mutect2, varscan2
- NDST1 | c.*1115G>T | 3'UTR (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- NDUFA5 | c.*4689_*4691del | 3'UTR (DEL) | VAF 38/103 reads (37%) | called by mutect2, pindel, varscan2
- NHEJ1 | c.*868C>G | 3'UTR (SNP) | VAF 16/19 reads (84%) | catalogued as rs575933532; called by muse, mutect2, varscan2
- NOTO | c.-48C>T | 5'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- OR10D1P | n.333C>T | RNA (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+347T>A | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+346T>A | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- PCDH7 | c.*226G>A | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*1842C>T | 3'UTR (SNP) | VAF 12/156 reads (8%) | catalogued as rs1320948408; called by muse, mutect2
- PEDS1-UBE2V1 | c.*43G>A | 3'UTR (SNP) | VAF 26/157 reads (17%) | catalogued as rs368141343; called by muse, mutect2, varscan2
- PEX11A | chr15:89690762 G>A | 5'Flank (SNP) | VAF 51/91 reads (56%) | catalogued as COSV51534079; called by muse, mutect2, varscan2
- PGK1 | c.*780C>A | 3'UTR (SNP) | VAF 49/110 reads (45%) | called by muse, varscan2
- PGK1 | c.*781C>T | 3'UTR (SNP) | VAF 51/113 reads (45%) | called by muse, varscan2
- PGR | c.2646+43G>C | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- PHACTR4 | chr1:28369669 C>T | 5'Flank (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- PHC1 | c.-57-39A>G | Intron (SNP) | VAF 107/196 reads (55%) | called by muse, mutect2, varscan2
- PIN4 | c.313-66C>T | Intron (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+1583C>T | Intron (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- PPARGC1A | c.234+1381C>T | Intron (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*7201G>C | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- PPM1A | c.952+1666G>C | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- PPM1F | c.355+1416A>G | Intron (SNP) | VAF 45/81 reads (56%) | called by muse, mutect2, varscan2
- PPP2R5E | c.*3007G>C | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- PSEN2 | chr1:226897626 C>T | 3'Flank (SNP) | VAF 22/274 reads (8%) | catalogued as rs868299391, COSV100423052; called by muse, mutect2
- RAB3C | c.*3318C>T | 3'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- RBM7 | c.*1325C>T | 3'UTR (SNP) | VAF 23/78 reads (29%) | catalogued as rs1431228334; called by muse, mutect2, varscan2
- RILPL1 | c.-37G>A | 5'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- ROBO2 | c.3554+183G>T | Intron (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- RSPO4 | c.*45A>T | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- SCN2B | c.*3419A>G | 3'UTR (SNP) | VAF 16/115 reads (14%) | catalogued as rs535652256; called by muse, mutect2, varscan2
- SERPINB13 | c.*1084C>T | 3'UTR (SNP) | VAF 14/191 reads (7%) | catalogued as rs755250989; called by muse, mutect2
- SH2D1B | c.*1394dup | 3'UTR (INS) | VAF 70/160 reads (44%) | called by mutect2, varscan2
- SLC30A4 | c.*3579A>T | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- SLC47A1 | c.*1365C>G | 3'UTR (SNP) | VAF 47/55 reads (85%) | called by muse, mutect2, varscan2
- SND1 | c.-147G>A | 5'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- SP110 | c.1590+128C>T | Intron (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- STK40 | c.1089+355T>C | Intron (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- STX6 | c.*3752C>T | 3'UTR (SNP) | VAF 39/82 reads (48%) | catalogued as rs763249474; called by muse, mutect2, varscan2
- SWAP70 | c.*1429G>T | 3'UTR (SNP) | VAF 62/93 reads (67%) | called by muse, mutect2, varscan2
- SYT14 | c.*307C>A | 3'UTR (SNP) | VAF 8/85 reads (9%) | catalogued as rs1185518776; called by muse, mutect2
- TAF7L | c.*787_*807del | 3'UTR (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- TCEA1 | c.232+300T>C | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- TDP2 | c.251+185C>T | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- TENT5D | c.*1252G>A | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- TF | chr3:133746143 C>T | 5'Flank (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- TGFA | chr2:70553843 G>A | 5'Flank (SNP) | VAF 10/22 reads (45%) | catalogued as rs1309611379; called by muse, mutect2, varscan2
- TMEM108 | c.1451-2863T>C | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- TNRC6B | c.*5819C>G | 3'UTR (SNP) | VAF 62/113 reads (55%) | catalogued as rs1001289255; called by muse, mutect2, varscan2
- TPD52 | chr8:80035787 G>A | 3'Flank (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- TPD52 | chr8:80035912 G>A | 3'Flank (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- TPD52 | chr8:80036033 G>A | 3'Flank (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.*2107T>A | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- TRIM9 | c.1603+319A>T | Intron (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- TTLL5 | c.3740+4377G>A | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- TULP4 | c.*4966G>C | 3'UTR (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- TXNL1 | chr18:56638600 C>T | 5'Flank (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- VPS13A | c.6378+237G>A | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- VPS54 | c.379-3287C>T | Intron (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- XKR4 | c.*1900G>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | catalogued as COSV59316473; called by muse, mutect2, varscan2
- YBX1P1 | n.850C>T | RNA (SNP) | VAF 41/46 reads (89%) | called by muse, mutect2, varscan2
- YY1 | c.*1603C>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- ZFP37 | c.*2740C>T | 3'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as rs765617290; called by muse, mutect2, varscan2
- ZNF252P | chr8:145005321 G>C | 5'Flank (SNP) | VAF 24/37 reads (65%) | catalogued as rs1201091102; called by muse, mutect2, varscan2
- ZNF789 | c.151+1640G>A | Intron (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- ZNF813 | c.*639G>C | 3'UTR (SNP) | VAF 22/406 reads (5%) | called by muse, mutect2
- ZNF84 | c.*3725T>A | 3'UTR (SNP) | VAF 58/104 reads (56%) | called by muse, mutect2, varscan2
